Somatic mutation profile of tumor specimen TCGA-HC-A631-01A (aliquot TCGA-HC-A631-01A-11D-A29Q-08) from TCGA case TCGA-HC-A631, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.8 years (24,749 days).
Specimen TCGA-HC-A631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3a1d047-6aa1-4dd1-8992-10df25d6189b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A631-10A (Blood Derived Normal), aliquot TCGA-HC-A631-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f0eca60-d8fc-45dd-8781-4a73772e94fa

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 21, Silent 11, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A1 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912935, CM020403, CM051895, COSV62611456; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 31/39 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC068580.4 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV52587055; called by muse, mutect2, varscan2
- ALDH1A1 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52789095; called by muse, mutect2, varscan2
- CDH9 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1340493492, COSV50251915; called by muse, mutect2, varscan2
- COQ8A | c.991T>G p.F331V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64656423; called by muse, mutect2
- ECE2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.245); catalogued as rs376213717; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62566648; called by muse, mutect2, varscan2
- ITGA3 | c.1202T>A p.I401N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50305992; called by muse, mutect2, varscan2
- LRRIQ3 | c.867+1G>T p.X289_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV63041074; called by muse, varscan2
- MECOM | c.2180G>A p.R727Q (on ENST00000468789 / NM_001105078.4; = p.R915Q on NM_004991.4) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1266973210, COSV52959477; called by muse, mutect2, varscan2
- NOVA2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV54355913, COSV54358787; called by muse, mutect2
- NTRK3 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as COSV58109287; called by muse, mutect2, varscan2
- PARP4 | c.3175C>T p.Q1059* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as rs1404755338, COSV67960376; called by muse, mutect2
- PKHD1 | c.11875A>G p.I3959V | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV64381405; called by muse, mutect2, varscan2
- PPP4R3B | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs199629271, COSV55401706; called by muse, mutect2, varscan2
- PTCH2 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs746520151, COSV64709648; called by muse, mutect2
- PTGS2 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV66568267; called by muse, mutect2, varscan2
- SCN1A | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as rs1553549679, CM113279, COSV57659617; called by muse, mutect2, varscan2
- SH3GL2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 40/46 reads (87%) | catalogued as COSV66047609; called by muse, mutect2, varscan2
- SLC6A5 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs146647574; called by muse, mutect2, varscan2
- SP3 | c.2029+2T>C p.X677_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as COSV59466075; called by muse, mutect2, varscan2
- TACC1 | c.2083T>G p.Y695D | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757860535, COSV52521395; called by muse, mutect2, varscan2
- TAS2R4 | c.548T>G p.L183W | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56093174; called by muse, mutect2, varscan2
- TRDN | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs757355311, COSV62113189; called by muse, mutect2, varscan2
- ZBTB44 | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.283); catalogued as COSV63536701; called by muse, mutect2
- ZNF134 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV68696143; called by muse, mutect2, varscan2
- PLPPR3 | c.99dup p.V34Rfs*23 | Frame Shift Ins (INS) | VAF 26/57 reads (46%) | called by mutect2, pindel, varscan2
- ABHD13 | c.21G>A p.L7= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV65534326; called by muse, mutect2, varscan2
- CCNJL | c.1140C>T p.T380= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs1159632553, COSV57443012; called by muse, mutect2, varscan2
- HHAT | c.48C>T p.G16= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV54791236; called by muse, mutect2, varscan2
- KCNJ5 | c.345G>T p.R115= | Silent (SNP) | VAF 60/121 reads (50%) | catalogued as COSV57963117; called by muse, mutect2, varscan2
- MTMR1 | c.417C>T p.V139= | Silent (SNP) | VAF 32/33 reads (97%) | catalogued as rs372879184, COSV64896952; called by muse, mutect2, varscan2
- PAPPA | c.1464C>T p.P488= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs535986686, COSV60277299, COSV60277357; called by muse, mutect2, varscan2
- PCDH18 | c.981A>G p.Q327= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV61266332, COSV61268397; called by muse, mutect2, varscan2
- RHO | c.678C>T p.L226= | Silent (SNP) | VAF 61/114 reads (54%) | catalogued as rs746223530, COSV56212382; called by muse, mutect2, varscan2
- SPIRE1 | c.1530C>A p.P510= (on ENST00000409402 / NM_001128626.2; = p.P496= on NM_020148.3) | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV59152174; called by muse, mutect2
- VCAN | c.1794G>A p.E598= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as rs760822691, COSV54096642; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ZIC1 | c.894C>T p.G298= | Silent (SNP) | VAF 11/191 reads (6%) | catalogued as COSV51550562, COSV51552405; called by muse, mutect2
